Somatic mutation profile of tumor specimen TCGA-WE-AAA3-06A (aliquot TCGA-WE-AAA3-06A-11D-A38G-08) from TCGA case TCGA-WE-AAA3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 85.1 years (31,099 days).
Specimen TCGA-WE-AAA3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88b0376d-cc34-4843-9faf-d08e020b5918.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-AAA3-10A (Blood Derived Normal), aliquot TCGA-WE-AAA3-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1585317b-751f-4988-bbf2-a93ab7809f84

The open-access MAF lists 453 somatic variants for this specimen: 280 protein-altering or splice-affecting, 161 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 161, Nonsense Mutation 19, Intron 4, Frame Shift Del 3, Splice Site 3, Splice Region 3, RNA 2, 3'UTR 2, 5'Flank 2, 3'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 45/100 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3664G>A p.V1222M | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100228803; called by muse, mutect2, varscan2
- ABCB11 | c.3037C>T p.H1013Y | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as COSV99791946; called by muse, mutect2, varscan2
- ABCC10 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99767095; called by muse, mutect2, varscan2
- ABCC9 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1212315529, COSV53966264; called by muse, mutect2, varscan2
- ACO1 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV100008006; called by muse, mutect2, varscan2
- ADAM21 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960850; called by muse, mutect2, varscan2
- ADAM7 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99443653; called by muse, mutect2, varscan2
- ADAMTS19 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV50735929, COSV99180420; called by muse, mutect2, varscan2
- ADAMTS6 | c.1364T>A p.F455Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.364); catalogued as COSV101124987; called by muse, mutect2, varscan2
- ADGRF5 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99345356; called by muse, mutect2, varscan2
- ALDH1A2 | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as COSV51078030, COSV99990634; called by muse, mutect2
- ANK3 | c.4819G>A p.E1607K | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV55050455; called by muse, mutect2, varscan2
- ANKFN1 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV59446429; called by muse, mutect2, varscan2
- ANKRA2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV99706998; called by muse, mutect2, varscan2
- ARHGAP15 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54493223; called by muse, mutect2, varscan2
- ARHGAP31 | c.3881C>T p.S1294L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs759632773, COSV99956952; called by muse, mutect2, varscan2
- ARHGEF37 | c.1812G>A p.M604I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100382049; called by muse, mutect2, varscan2
- ASAH2 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100269891; called by muse, mutect2, varscan2
- ATP13A5 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV60866913; called by muse, mutect2, varscan2
- BPIFC | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99322081; called by muse, mutect2, varscan2
- CA7 | c.326A>C p.H109P | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100623755; called by muse, mutect2, varscan2
- CACNA1S | c.5120C>T p.P1707L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1174377440, COSV100754901; called by muse, mutect2, varscan2
- CACNB1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.039); catalogued as rs746595958, COSV59998237; called by muse, mutect2, varscan2
- CALCR | c.693C>G p.D231E (on ENST00000649521 / NM_001164737.2; = p.D215E on NM_001742.4) | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV64010599; called by muse, mutect2, varscan2
- CALR3 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV99522137; called by muse, mutect2, varscan2
- CCDC70 | c.559T>A p.F187I | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.238); catalogued as COSV99665347; called by muse, mutect2, varscan2
- CCDC74B | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100134789, COSV60100611; called by muse, mutect2, varscan2
- CCNB1IP1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs559090444, COSV62303448; called by muse, mutect2, varscan2
- CD200R1 | c.406A>T p.T136S (on ENST00000471858 / NM_170780.3; = p.T159S on NM_138806.4) | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV99867091; called by muse, mutect2, varscan2
- CD300E | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as COSV60789763; called by muse, mutect2, varscan2
- CD7 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.163); catalogued as COSV53941150, COSV99486190; called by muse, mutect2, varscan2
- CD93 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55667054; called by muse, mutect2, varscan2
- CDH12 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs765635488, COSV66386124; called by muse, mutect2, varscan2
- CFAP61 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99844361; called by muse, mutect2, varscan2
- CHST8 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs766372648, COSV99380984; called by muse, mutect2, varscan2
- CLEC14A | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV100643539; called by muse, mutect2, varscan2
- CLEC14A | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); catalogued as rs1286577532, COSV60564051; called by muse, mutect2, varscan2
- CNTNAP2 | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs144003410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A3 | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59257379; called by muse, mutect2, varscan2
- COL5A2 | c.4279G>A p.G1427R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100880171; called by muse, mutect2, varscan2
- COLQ | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101082159; called by muse, mutect2, varscan2
- CORIN | c.2394G>A p.M798I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1469333413, COSV99903407; called by muse, mutect2, varscan2
- COX7B2 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV57214432; called by muse, mutect2, varscan2
- CPNE6 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV99393314; called by muse, mutect2, varscan2
- CPQ | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99611468; called by muse, mutect2, varscan2
- CR2 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV100889602; called by muse, mutect2, varscan2
- CRMP1 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560508405, COSV61478684; called by muse, varscan2
- CSMD1 | c.8017G>A p.E2673K (on ENST00000520002; = p.E2672K on NM_033225.6) | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as rs762951826, COSV59312630; called by muse, mutect2, varscan2
- CSMD3 | c.4616G>A p.R1539Q (on ENST00000297405 / NM_001363185.1; = p.R1435Q on NM_052900.3) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1472368863, COSV52210021; called by muse, mutect2, varscan2
- CYP51A1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs372185409; called by muse, mutect2, varscan2
- DCC | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs1472223303, COSV100499330; called by muse, mutect2
- DHX40 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1165876568, COSV99232876; called by mutect2, varscan2
- DLG3 | c.1939G>A p.E647K (on ENST00000374360 / NM_021120.4; = p.E342K on NM_020730.3) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99529416; called by muse, mutect2, varscan2
- DLK2 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs757553066, COSV55087704, COSV99767097; called by muse, mutect2, varscan2
- DMP1 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.055); catalogued as COSV99218640; called by muse, mutect2, varscan2
- DNAH5 | c.9730G>A p.E3244K | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV54223192, COSV54229346; called by muse, mutect2, varscan2
- DNAH5 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs267600373, COSV99448355; called by muse, mutect2, varscan2
- DOCK3 | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs780118452, COSV56515698; called by muse, mutect2, varscan2
- DSCAM | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs765431927, COSV68022737; called by muse, mutect2, varscan2
- DSP | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV101131237; called by muse, mutect2, varscan2
- DSP | c.8143G>A p.E2715K | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.066); catalogued as COSV60940408; called by muse, mutect2, varscan2
- DYNC1H1 | c.6394C>T p.P2132S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV100794761, COSV100795715; called by muse, mutect2
- EHD1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs1333087395, COSV57734430; called by muse, mutect2, varscan2
- EIF2D | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV99662704; called by muse, mutect2
- EIF3E | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as COSV55203011; called by muse, mutect2, varscan2
- ELAVL3 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100820737; called by muse, mutect2, varscan2
- ELMO1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100164060; called by muse, mutect2, varscan2
- ENAM | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101253039; called by muse, mutect2, varscan2
- ENPP7 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as rs928548411, COSV100093323; called by muse, mutect2, varscan2
- ENTPD7 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.74); catalogued as rs770245006, COSV100978391; called by muse, mutect2, varscan2
- EPB41 | c.1522C>T p.R508* (on ENST00000343067 / NM_001166005.2; = p.R299* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV100548243; called by muse, mutect2, varscan2
- EPPK1 | c.3473G>A p.R1158Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs781805386, COSV101599805, COSV101599974; called by muse, mutect2, varscan2
- ERN2 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV56832997, COSV56836911; called by muse, mutect2, varscan2
- EYA1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58159030; called by muse, mutect2, varscan2
- FABP6 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs368440281; called by muse, mutect2, varscan2
- FAT4 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as COSV101272247; called by muse, mutect2, varscan2
- FBN2 | c.7015G>A p.E2339K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV99326648; called by muse, mutect2, varscan2
- FER1L6 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV67548784; called by muse, mutect2, varscan2
- FER1L6 | c.3067G>A p.G1023R | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101205738, COSV67552892; called by muse, mutect2, varscan2
- FERMT1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99451430; called by muse, mutect2, varscan2
- FGF6 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 58/105 reads (55%) | catalogued as COSV57405659; called by muse, mutect2, varscan2
- FLNB | c.4140T>G p.D1380E | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99912699; called by muse, mutect2, varscan2
- FLRT1 | c.1364G>A p.W455* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV99735029; called by muse, mutect2, varscan2
- FNDC1 | c.4826G>A p.R1609Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51933203; called by muse, mutect2, varscan2
- FOXN1 | c.1501C>T p.H501Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99881178; called by muse, mutect2, varscan2
- FRMPD1 | c.2054G>A p.W685* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as rs867909862, COSV100899254, COSV100899538; called by muse, mutect2, varscan2
- FSIP1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV100618040; called by muse, mutect2, varscan2
- FUBP1 | c.1205T>C p.I402T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99628417; called by muse, mutect2, varscan2
- GAB3 | c.1718G>A p.S573N | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100850510; called by muse, mutect2, varscan2
- GDPD5 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375384270; called by muse, mutect2
- GJA10 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV65355572; called by muse, mutect2, varscan2
- GLUD1 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99518066; called by muse, mutect2, varscan2
- GPR174 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV52131430; called by muse, mutect2, varscan2
- GPRC6A | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59952111; called by muse, mutect2, varscan2
- GREB1 | c.3361A>G p.R1121G | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV99302735; called by muse, mutect2, varscan2
- GRIA1 | c.1560A>T p.K520N | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99599243; called by muse, mutect2, varscan2
- GRIA3 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52049378; called by muse, mutect2, varscan2
- GRM3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); catalogued as COSV64469393; called by muse, mutect2, varscan2
- GSDMC | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs375510820; called by muse, mutect2, varscan2
- GSE1 | c.2833A>C p.K945Q | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV99496396; called by muse, mutect2, varscan2
- HERC1 | c.9667C>T p.R3223* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV71247813; called by muse, mutect2, varscan2
- HPCAL4 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100864768; called by muse, mutect2, varscan2
- HRH1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV101229056; called by muse, mutect2, varscan2
- HS3ST4 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as rs760401237, COSV58810277; called by muse, mutect2, varscan2
- HSP90AA1 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs868513330, COSV100593121; called by muse, mutect2, varscan2
- IGFN1 | c.1771G>A p.G591S (on ENST00000295591 / NM_001367841.1; = p.G3048S on NM_001164586.2) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as rs757862052, COSV99811908; called by muse, mutect2, varscan2
- IGSF1 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100812031; called by muse, mutect2, varscan2
- IL10RA | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1290851371, COSV99922978; called by muse, mutect2, varscan2
- ITPRID2 | c.3320C>T p.S1107F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1488140918, COSV100238140; called by muse, mutect2, varscan2
- KCNB2 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73053060; called by muse, varscan2
- KCNG1 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100856933; called by muse, mutect2, varscan2
- KCNH7 | c.2962+1G>A p.X988_splice | Splice Site (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100147537; called by muse, mutect2, varscan2
- KEL | c.1482A>T p.E494D | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100787013; called by muse, mutect2, varscan2
- KIAA1217 | c.4870G>A p.E1624K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748580908, COSV56815372; called by muse, mutect2, varscan2
- KIF15 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100392742; called by muse, mutect2, varscan2
- KIF19 | c.2447G>A p.S816N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as COSV100739048; called by muse, mutect2, varscan2
- KRT28 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100137507; called by muse, mutect2, varscan2
- KRTAP5-10 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1450707093, COSV64794084; called by muse, varscan2
- L3MBTL4 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs780118510, COSV99528489; called by muse, mutect2, varscan2
- LATS2 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV66878807; called by muse, mutect2, varscan2
- LCT | c.2594C>A p.S865Y | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV99929168; called by muse, mutect2, varscan2
- LHX9 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 53/369 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV100435794; called by muse, mutect2, varscan2
- LIPI | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV60708652; called by muse, mutect2, varscan2
- LPCAT4 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs759805853, COSV59218548; called by muse, mutect2, varscan2
- LRG1 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100014790; called by muse, mutect2, varscan2
- LRP1B | c.6485G>A p.G2162E | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211665488, COSV67287170; called by muse, mutect2, varscan2
- LTB | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV101438044; called by muse, mutect2
- MAGEC3 | c.1726G>T p.G576W | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53577696; called by muse, mutect2, varscan2
- MDC1 | c.61A>C p.S21R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100902736; called by muse, mutect2, varscan2
- ME1 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs145105900; called by muse, mutect2, varscan2
- MEGF8 | c.3389C>T p.P1130L (on ENST00000251268 / NM_001271938.2; = p.P1063L on NM_001410.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99235635; called by mutect2, varscan2
- MFF | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.562); catalogued as COSV100449307; called by muse, mutect2, varscan2
- MMRN1 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs573195123, COSV99306939; called by muse, mutect2, varscan2
- MSH4 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1329485122, COSV99591333; called by muse, mutect2, varscan2
- MSR1 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026970, COSV50513955; called by muse, mutect2
- MSR1 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs774345152, COSV50510265; called by muse, mutect2, varscan2
- MUC16 | c.23047G>A p.E7683K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.047); catalogued as COSV67477173, COSV67492246; called by muse, mutect2, varscan2
- MUC16 | c.17755C>T p.P5919S | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV67501293; called by muse, mutect2, varscan2
- MUC3A | c.8131C>T p.P2711S | Missense Mutation (SNP) | VAF 101/594 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.982); catalogued as COSV60226836; called by muse, mutect2, varscan2
- MXRA5 | c.3654G>A p.M1218I | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV99476534; called by muse, mutect2, varscan2
- MYH1 | c.4571G>A p.G1524E | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV56844131; called by muse, mutect2, varscan2
- MYH8 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV101238365; called by muse, mutect2, varscan2
- MYO16 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99193807; called by muse, mutect2, varscan2
- MYO18B | c.7049C>T p.S2350F | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868770360, COSV59129645; called by muse, mutect2, varscan2
- MYO1F | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100596593, COSV57792110; called by muse, mutect2, varscan2
- MYOM1 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs762430543, COSV55291060; called by muse, mutect2
- NDST2 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.741); catalogued as COSV100013854; called by muse, mutect2, varscan2
- NDST4 | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV52109110, COSV52113122; called by muse, mutect2
- NEB | c.11935G>A p.E3979K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as COSV99420095; called by muse, mutect2
- NEB | c.6331A>G p.T2111A | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs772892315, COSV99420104; called by muse, mutect2, varscan2
- NHSL2 | c.2048G>A p.G683D (on ENST00000510661; = p.G1049D on NM_001013627.2) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV101029998; called by muse, mutect2, varscan2
- NIPBL | c.6632A>G p.E2211G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV99240046; called by muse, mutect2, varscan2
- NLRP4 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 42/160 reads (26%) | catalogued as COSV100016106, COSV100016860; called by muse, mutect2, varscan2
- NLRP9 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60461569; called by muse, mutect2, varscan2
- NPAT | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV99585948; called by muse, mutect2, varscan2
- NPPA | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56741654; called by muse, mutect2, varscan2
- NPPB | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100916089; called by muse, mutect2, varscan2
- NPY5R | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV100642746; called by muse, mutect2, varscan2
- NR2F1 | c.998G>C p.C333S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV100504638; called by muse, mutect2, varscan2
- NR2F1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV59068177; called by muse, mutect2, varscan2
- NRXN3 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539329038, COSV73583739; called by muse, mutect2, varscan2
- OBSCN | c.21098C>T p.P7033L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100803089; called by muse, mutect2, varscan2
- OR10G9 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs747156389, COSV66685997, COSV66686833; called by muse, mutect2, varscan2
- OR11H1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53271636; called by muse, mutect2, varscan2
- OR2T33 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.044); catalogued as COSV100531794, COSV100532074; called by muse, mutect2, varscan2
- OR5AS1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57982912; called by muse, mutect2
- OR5AS1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs186626466; called by muse, mutect2, varscan2
- OR5H15 | c.545T>G p.I182S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100736652; called by muse, mutect2, varscan2
- OSMR | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.539); catalogued as rs1278259166, COSV99953017; called by muse, mutect2, varscan2
- P3H2 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs769955962, COSV100077435; called by muse, mutect2, varscan2
- PAX6 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD973065, COSV53793659; called by muse, mutect2, varscan2
- PCDH15 | c.5185G>A p.E1729K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0.03); catalogued as COSV100903760; called by muse, mutect2, varscan2
- PCDH8 | c.3133C>T p.Q1045* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV100131458; called by muse, mutect2, varscan2
- PCDHA6 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as rs150883390, COSV65355904; called by muse, mutect2, varscan2
- PCDHB4 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV99522047; called by muse, mutect2, varscan2
- PCP4 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100150641; called by muse, mutect2, varscan2
- PEG3 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs760661733, COSV55643251; called by muse, mutect2, varscan2
- PENK | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1563485616, COSV59242881; called by muse, mutect2, varscan2
- PKHD1L1 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1193899058, COSV101005959; called by muse, mutect2, varscan2
- PLA2G6 | c.894G>A p.E298= | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100140280, COSV59269896; called by muse, mutect2
- PLCH1 | c.1381G>A p.D461N (on ENST00000340059 / NM_001130960.2; = p.D473N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100396425; called by muse, mutect2, varscan2
- PLK3 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 21/46 reads (46%) | catalogued as rs763486117, COSV59499501; called by muse, mutect2, varscan2
- PNOC | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as COSV57283669; called by muse, mutect2, varscan2
- PON3 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV99672386; called by muse, mutect2, varscan2
- PROK2 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99816921, COSV99816944; called by muse, mutect2, varscan2
- PRRC2C | c.3813T>G p.S1271R (on ENST00000367742; = p.S1269R on NM_015172.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100145095; called by muse, mutect2, varscan2
- PRSS53 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99762210; called by muse, mutect2, varscan2
- PSAPL1 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV100040445; called by muse, varscan2
- PSD4 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs750617134, COSV99831031; called by muse, mutect2, varscan2
- PTPRC | c.2970G>C p.E990D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as COSV100722482; called by muse, mutect2, varscan2
- QSER1 | c.604C>T p.Q202* (on ENST00000399302; = p.Q331* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV101234813; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs137980905; called by muse, mutect2, varscan2
- RAB6A | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100154959; called by muse, mutect2, varscan2
- RASGRP1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV100171882; called by muse, mutect2, varscan2
- ROS1 | c.6793G>A p.E2265K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV100876919; called by muse, mutect2, varscan2
- RP1 | c.3988G>A p.D1330N | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs756252290, COSV55117390; called by muse, mutect2, varscan2
- RPS21 | c.211del p.R71Dfs*27 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as COSV54158368; called by mutect2, pindel, varscan2
- SAMD9L | c.4345G>A p.E1449K | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as COSV100560597; called by muse, mutect2, varscan2
- SAMD9L | c.2221C>T p.H741Y | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59080800; called by muse, mutect2, varscan2
- SAXO2 | c.371A>G p.Q124R | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs753132794, COSV100255665; called by muse, mutect2, varscan2
- SCAF4 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99741290; called by muse, mutect2, varscan2
- SCN10A | c.5544G>A p.W1848* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV101479346; called by muse, mutect2, varscan2
- SCN3A | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV51823723; called by muse, mutect2, varscan2
- SERINC4 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as COSV99988364; called by muse, mutect2, varscan2
- SERPINA7 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100568274; called by muse, mutect2, varscan2
- SERPIND1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); catalogued as rs1462976369, COSV99300159; called by muse, mutect2, varscan2
- SEZ6L | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV99961822; called by muse, mutect2, varscan2
- SGF29 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV100187100; called by muse, mutect2, varscan2
- SHCBP1L | c.1905G>A p.M635I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.061); catalogued as COSV62354242, COSV62355876; called by muse, mutect2, varscan2
- SHD | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV100010217; called by muse, mutect2, varscan2
- SIGLEC11 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs771866761, COSV70221874, COSV70222094; called by muse, mutect2, varscan2
- SIN3B | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV56132600; called by muse, varscan2
- SLC15A2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV99815406; called by muse, mutect2, varscan2
- SLC25A31 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs755053928, COSV55420047; called by muse, mutect2, varscan2
- SLC26A7 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.239); catalogued as COSV52592753; called by muse, mutect2, varscan2
- SLFN11 | c.2673A>C p.Q891H | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs766381391, COSV57699423; called by muse, mutect2, varscan2
- SPEF2 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV61544918, COSV61545982; called by muse, mutect2, varscan2
- SPHKAP | c.2860G>A p.G954R | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100764026; called by muse, mutect2, varscan2
- SPTA1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63751581; called by muse, mutect2, varscan2
- SRCIN1 | c.3292C>T p.R1098C (on ENST00000621492; = p.R1064C on NM_025248.3) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757306777; called by muse, mutect2, varscan2
- SSB | c.66+1G>A p.X22_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as rs1288907434, COSV99642168; called by muse, mutect2
- ST8SIA5 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 23/84 reads (27%) | PolyPhen probably damaging (0.916); catalogued as rs1235483250, COSV100164639, COSV59331093; called by muse, mutect2, varscan2
- STAC | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99829848; called by muse, mutect2, varscan2
- STOX1 | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs765996352, COSV100057765; called by muse, mutect2, varscan2
- STXBP5L | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV99873393; called by muse, mutect2, varscan2
- SYNPR | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99887343, COSV99888094; called by muse, mutect2
- SYT10 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as COSV57339260; called by muse, mutect2, varscan2
- TACC3 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100508641; called by muse, mutect2, varscan2
- TAFA4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99806808; called by muse, mutect2, varscan2
- TAT | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV100587456, COSV100587590; called by muse, mutect2, varscan2
- TBC1D19 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as rs1213570058, COSV99336227; called by muse, mutect2, varscan2
- TBX4 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.261); catalogued as COSV99540106; called by muse, mutect2, varscan2
- TENM2 | c.4328A>T p.N1443I (on ENST00000518659 / NM_001122679.2; = p.N1204I on NM_001080428.3) | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV101318485; called by muse, mutect2, varscan2
- TGFBI | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761157035; called by muse, mutect2, varscan2
- TGFBI | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100526422, COSV59354038; called by muse, mutect2, varscan2
- THEMIS | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100965335; called by muse, mutect2, varscan2
- TINAG | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773073432, COSV52510947, COSV99449574; called by muse, mutect2, varscan2
- TJP3 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99515973; called by muse, mutect2, varscan2
- TMC5 | c.1149G>A p.R383= (on ENST00000396229 / NM_001105248.1; = p.R137= on NM_024780.5) | Splice Region (SNP) | VAF 22/66 reads (33%) | catalogued as COSV54901278; called by muse, mutect2, varscan2
- TMEM67 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV100019069; called by muse, mutect2, varscan2
- TMPRSS11F | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100678420; called by muse, mutect2, varscan2
- TNFSF10 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV53843602, COSV99577662; called by muse, mutect2, varscan2
- TNIK | c.3218G>A p.R1073Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99456595; called by muse, mutect2, varscan2
- TNR | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as COSV54886541; called by muse, mutect2, varscan2
- TNXB | c.8630G>A p.R2877H (on ENST00000647633; = p.R2630H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs374865424; ClinVar: likely benign; called by muse, mutect2, varscan2
- TPRX1 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100445643; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as COSV99160929; called by muse, mutect2, varscan2
- TRANK1 | c.5145G>A p.W1715* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100082489; called by muse, mutect2, varscan2
- TRHR | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV61236389; called by muse, mutect2, varscan2
- TRPM4 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53268818; called by muse, mutect2, varscan2
- TTN | c.98317G>A p.E32773K (on ENST00000591111; = p.E25349K on NM_003319.4) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | PolyPhen probably damaging (0.994); catalogued as COSV60223044; called by muse, mutect2, varscan2
- TTN | c.48625G>A p.E16209K (on ENST00000591111; = p.E8785K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | PolyPhen benign (0.385); catalogued as COSV100605724, COSV100637223; called by muse, mutect2, varscan2
- TTN | c.43447G>A p.E14483K (on ENST00000591111; = p.E7059K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | PolyPhen probably damaging (0.994); catalogued as rs754392831, COSV100605732, COSV60041068; called by muse, mutect2, varscan2
- TTN | c.27893G>A p.G9298E (on ENST00000591111; = p.G8371E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | PolyPhen probably damaging (1); catalogued as COSV100605736; called by muse, mutect2, varscan2
- TTN | c.4583G>A p.W1528* (on ENST00000591111; = p.W1482* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100605739, COSV60253571; called by muse, mutect2, varscan2
- TUBAL3 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV100990525; called by muse, mutect2, varscan2
- UBA7 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100339718; called by muse, mutect2, varscan2
- UFD1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 148/323 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99597342; called by muse, mutect2, varscan2
- UGT2B11 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV101485240; called by muse, mutect2, varscan2
- VCAN | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99425433; called by muse, mutect2, varscan2
- VGLL3 | c.127-1G>A p.X43_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV67353821; called by muse, mutect2, varscan2
- WARS1 | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100690131; called by muse, mutect2, varscan2
- WNK3 | c.4017G>A p.V1339= | Splice Region (SNP) | VAF 22/38 reads (58%) | catalogued as COSV100671180; called by muse, mutect2, varscan2
- XKR4 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59312916; called by muse, mutect2, varscan2
- ZFAND4 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1417323004, COSV58897410; called by muse, mutect2, varscan2
- ZHX2 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs267601758, COSV100072877; called by muse, mutect2, varscan2
- ZNF174 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV51903408; called by muse, mutect2, varscan2
- ZNF285 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100449959; called by muse, mutect2, varscan2
- ZNF331 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV99467158; called by muse, mutect2, varscan2
- ZNF331 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV53476126; called by muse, mutect2, varscan2
- ZNF514 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99727684; called by muse, mutect2, varscan2
- ZP2 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.132); catalogued as COSV54812593; called by muse, mutect2, varscan2
- FBN1 | c.5261_5266del p.G1754_F1755del | In Frame Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- IMMT | c.1727del p.L576* | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- LILRA6 | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LMOD2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRAMEF17 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- VIRMA | c.2473_2474del p.L825Yfs*14 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | called by mutect2, pindel, varscan2
- ACACB | c.1632C>T p.F544= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1162445558, COSV100622708; called by muse, mutect2, varscan2
- ACKR1 | c.792C>T p.F264= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs367719902; called by muse, mutect2, varscan2
- ACKR1 | c.793C>T p.L265= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV100929524; called by muse, mutect2, varscan2
- ACLY | c.1782C>T p.I594= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs1555628518, COSV100709636; called by muse, mutect2, varscan2
- ACTR5 | c.1659C>T p.T553= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as COSV99709982, COSV99710272; called by muse, mutect2, varscan2
- ADCY8 | c.1938A>C p.S646= | Silent (SNP) | VAF 60/269 reads (22%) | catalogued as COSV99651683; called by muse, mutect2, varscan2
- AIM2 | c.18G>A p.K6= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- AIRE | c.660C>T p.S220= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV99381083; called by muse, mutect2
- ARHGAP44 | c.762G>A p.G254= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV99310506; called by muse, mutect2, varscan2
- ASAH2 | c.1902C>T p.F634= | Silent (SNP) | VAF 39/163 reads (24%) | called by muse, mutect2, varscan2
- ASXL3 | c.3306C>T p.I1102= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs1042294069, COSV52459055, COSV99324379; called by muse, mutect2, varscan2
- ATG9A | c.1320G>T p.V440= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99521770; called by muse, mutect2, varscan2
- BAIAP3 | c.1426C>T p.L476= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100181348; called by muse, mutect2
- BCAN | c.1113C>T p.N371= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100228028; called by muse, mutect2, varscan2
- BNIP5 | c.153G>A p.T51= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as rs756773124, COSV101465103; called by muse, mutect2, varscan2
- BRINP1 | c.762G>A p.G254= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs778004789, COSV99775129; called by muse, mutect2, varscan2
- BRINP1 | c.276C>T p.R92= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs1275090059, COSV56294965; called by muse, mutect2, varscan2
- BTBD11 | c.2496C>T p.I832= (on ENST00000280758 / NM_001018072.2; = p.I369= on NM_001017523.2) | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs758128980, COSV55024804; called by muse, mutect2, varscan2
- C6orf15 | c.111C>T p.S37= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as COSV99456798; called by muse, mutect2, varscan2
- C9orf131 | c.2376G>A p.K792= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as COSV100398030, COSV100398293; called by muse, mutect2, varscan2
- CACNA1A | c.1038C>T p.I346= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs527246699, COSV64191162; ClinVar: uncertain significance; called by muse, mutect2
- CDC23 | c.363C>T p.S121= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV101202995; called by muse, mutect2, varscan2
- CDC42BPB | c.4668C>T p.F1556= | Silent (SNP) | VAF 81/252 reads (32%) | catalogued as rs745550984, COSV63475628; called by muse, mutect2, varscan2
- CDH23 | c.5844C>T p.F1948= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1327732062, COSV99820301; called by muse, mutect2, varscan2
- CELF5 | c.1278C>T p.I426= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV99485871; called by muse, mutect2, varscan2
- CHRNB2 | c.858C>T p.I286= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs865998992, COSV63808978; called by muse, mutect2, varscan2
- CHST8 | c.207G>A p.K69= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99380982; called by muse, mutect2, varscan2
- COL19A1 | c.348G>A p.R116= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs780803744, COSV59570453; called by muse, mutect2, varscan2
- COL5A2 | c.3708C>T p.I1236= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100880173; called by muse, mutect2
- CTNND2 | c.339C>T p.I113= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs374819899, COSV58864314; called by muse, mutect2, varscan2
- DGAT2 | c.1131C>T p.F377= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs148751558; called by muse, mutect2, varscan2
- DHRS4 | c.144C>T p.I48= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as rs756725350, COSV100365853; called by muse, mutect2, varscan2
- DNAH8 | c.2865G>A p.K955= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100544457, COSV100546257; called by muse, mutect2, varscan2
- DOCK2 | c.804G>A p.K268= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV99911582; called by muse, mutect2, varscan2
- DRD1 | c.535C>T p.L179= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs1561637048, COSV101192428; called by muse, mutect2, varscan2
- EHD1 | c.519C>T p.A173= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs144914499; called by muse, mutect2, varscan2
- ELMO1 | c.1809C>T p.S603= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV60326231; called by muse, mutect2, varscan2
- EPHA3 | c.2295C>T p.F765= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs773426684, COSV60694998; called by muse, mutect2, varscan2
- ESYT3 | c.2631G>A p.E877= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs777323654, COSV101272653; called by muse, mutect2, varscan2
- EVPL | c.2997G>A p.K999= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV100044349; called by muse, mutect2, varscan2
- FAM124A | c.513C>T p.I171= (on ENST00000322475 / NM_001242312.2; = p.I207= on NM_145019.4) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV54480238; called by muse, mutect2, varscan2
- FAM20B | c.477C>T p.F159= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV99762271; called by muse, mutect2, varscan2
- FAM83H | c.2472C>T p.G824= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100567813; called by muse, mutect2
- FARSA | c.690C>T p.V230= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100108774; called by muse, mutect2, varscan2
- FFAR4 | c.900C>T p.I300= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV101012254; called by muse, mutect2, varscan2
- FLT4 | c.393C>T p.F131= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs267600585, COSV56117608, COSV56119531; called by muse, mutect2, varscan2
- GDPD5 | c.1458C>T p.S486= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV61130254; called by muse, mutect2
- GGTLC2 | c.294C>T p.F98= | Silent (SNP) | VAF 82/346 reads (24%) | catalogued as rs866773529, COSV67854146; called by muse, mutect2, varscan2
- GLYR1 | c.1317C>T p.I439= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100424189; called by muse, mutect2, varscan2
- GNAZ | c.1011C>T p.F337= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs139659965; called by muse, mutect2, varscan2
- GNG4 | c.219C>T p.T73= | Silent (SNP) | VAF 114/241 reads (47%) | catalogued as rs774981261, COSV100782497; called by muse, mutect2, varscan2
- GPR153 | c.624C>T p.D208= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100928496; called by muse, mutect2
- GTF3C4 | c.1737C>T p.F579= | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as COSV100935982; called by muse, mutect2, varscan2
- HAPLN3 | c.129C>T p.L43= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1198577484, COSV62087006; called by muse, mutect2, varscan2
- HDLBP | c.2148C>T p.L716= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100190325; called by muse, mutect2, varscan2
- HECTD4 | c.8628C>T p.F2876= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1168253720, COSV101107252; called by muse, mutect2
- HHLA2 | c.1078C>T p.L360= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV63317807; called by muse, mutect2, varscan2
- IGF2BP2 | c.942G>A p.Q314= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV100649008; called by muse, mutect2, varscan2
- IGLV3-12 | c.225G>A p.G75= | Silent (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- IL21R | c.108C>T p.I36= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs1247440660, COSV100559870; called by muse, mutect2, varscan2
- ILDR1 | c.1215C>T p.S405= (on ENST00000344209 / NM_001199799.2; = p.S361= on NM_175924.4) | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99878207; called by muse, mutect2, varscan2
- ITIH6 | c.2532C>T p.I844= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as COSV99513155; called by muse, mutect2, varscan2
- ITK | c.801C>T p.S267= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101346683; called by muse, mutect2
- ITPRID2 | c.2547C>T p.I849= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs1362909281, COSV57476484; called by muse, mutect2, varscan2
- KCNB2 | c.1182G>A p.G394= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as COSV73049639; called by muse, varscan2
- KCNJ4 | c.1116C>T p.C372= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100341139; called by muse, mutect2, varscan2
- KCNK10 | c.513G>A p.G171= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as rs868674222, COSV100068084; called by muse, mutect2, varscan2
- KDM5B | c.3972A>T p.S1324= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99350439; called by muse, mutect2, varscan2
- LAMA3 | c.8730C>T p.V2910= (on ENST00000313654 / NM_198129.4; = p.V1301= on NM_000227.6) | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99334505; called by muse, mutect2, varscan2
- LGR5 | c.2127C>T p.S709= | Silent (SNP) | VAF 86/141 reads (61%) | catalogued as COSV57011221, COSV99877549; called by muse, mutect2, varscan2
- LMO2 | c.138C>T p.I46= (on ENST00000395833 / NM_001142315.2; = p.I115= on NM_005574.4) | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs533717865, COSV99137805; called by muse, mutect2, varscan2
- LRFN2 | c.285C>T p.S95= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100599433; called by muse, mutect2, varscan2
- MAN1C1 | c.1284C>G p.V428= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs749580897, COSV99848126; called by muse, mutect2, varscan2
- MAPK4 | c.480G>A p.E160= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV101245345; called by muse, mutect2, varscan2
- MAT2B | c.906C>T p.T302= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV99796611; called by muse, mutect2, varscan2
- MAVS | c.162C>T p.T54= | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as rs1173161312, COSV100816292; called by muse, mutect2, varscan2
- MCC | c.435G>A p.R145= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV101342723; called by muse, mutect2, varscan2
- MCTP2 | c.2385C>T p.F795= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV63295371; called by muse, mutect2, varscan2
- MDC1 | c.60C>G p.S20= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100902737; called by muse, mutect2, varscan2
- MMEL1 | c.321G>A p.P107= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs150441473; called by muse, mutect2, varscan2
- MN1 | c.3132C>T p.F1044= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as rs1351279074, COSV56556159; called by muse, mutect2, varscan2
- MSRA | c.492C>T p.T164= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100412772; called by muse, mutect2, varscan2
- MTAP | c.900C>T p.F300= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1004191591, COSV101289210; called by muse, mutect2, varscan2
- MUC16 | c.31593C>T p.F10531= | Silent (SNP) | VAF 121/332 reads (36%) | catalogued as COSV67448627; called by muse, mutect2, varscan2
- MUC16 | c.3660G>A p.L1220= | Silent (SNP) | VAF 98/303 reads (32%) | catalogued as rs1036060825, COSV101199402; called by muse, mutect2, varscan2
- MYBL2 | c.1299G>A p.L433= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV99406219; called by muse, mutect2, varscan2
- MYH6 | c.4680C>T p.I1560= | Silent (SNP) | VAF 64/170 reads (38%) | catalogued as COSV100676453, COSV100676867; called by muse, mutect2, varscan2
- MYLK2 | c.1323G>A p.V441= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV101044750; called by muse, mutect2, varscan2
- MYO18B | c.1719C>T p.V573= | Silent (SNP) | VAF 43/234 reads (18%) | catalogued as rs371193611, COSV100123313; called by muse, mutect2, varscan2
- NAXD | c.828C>T p.L276= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99959571; called by muse, mutect2, varscan2
- NCAN | c.1953C>T p.S651= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as COSV99387034; called by muse, mutect2, varscan2
- NETO1 | c.633G>A p.R211= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as COSV100198519; called by muse, mutect2, varscan2
- NOP56 | c.415C>T p.L139= | Silent (SNP) | VAF 124/300 reads (41%) | catalogued as COSV100250041; called by muse, mutect2, varscan2
- NRIP1 | c.1926C>T p.S642= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as COSV59658997; called by muse, mutect2, varscan2
- NRROS | c.1569C>T p.L523= | Silent (SNP) | VAF 67/202 reads (33%) | catalogued as COSV100145450; called by muse, mutect2, varscan2
- NSUN6 | c.1110T>C p.Y370= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV101045551; called by muse, mutect2, varscan2
- NUBP2 | c.813C>T p.P271= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99236467; called by muse, mutect2
- OCRL | c.2148C>T p.S716= | Silent (SNP) | VAF 119/248 reads (48%) | catalogued as COSV100843406; called by muse, mutect2, varscan2
- ONECUT3 | c.1113C>T p.S371= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV66639776; called by muse, mutect2
- OR13C4 | c.342C>T p.L114= | Silent (SNP) | VAF 71/151 reads (47%) | catalogued as rs1207691866, COSV52925884; called by muse, mutect2, varscan2
- OR14J1 | c.465C>T p.L155= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as rs150184697; called by muse, mutect2, varscan2
- OR4K13 | c.675T>C p.V225= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100237709; called by muse, mutect2, varscan2
- OR6N1 | c.144G>A p.V48= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs762892471, COSV100625138; called by muse, mutect2, varscan2
- OR7G3 | c.639G>A p.G213= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV59640495; called by muse, mutect2, varscan2
- PCDH8 | c.3132G>A p.L1044= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as rs756973241, COSV100131461; called by muse, mutect2, varscan2
- PEG3 | c.330G>A p.K110= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV55630766; called by muse, mutect2, varscan2
- PLA2G2D | c.114C>T p.I38= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100908017; called by muse, mutect2, varscan2
- PLCB4 | c.2070C>T p.F690= | Silent (SNP) | VAF 51/190 reads (27%) | catalogued as COSV99595088; called by muse, mutect2, varscan2
- PORCN | c.294C>T p.F98= | Silent (SNP) | VAF 65/129 reads (50%) | catalogued as COSV100400408; called by muse, mutect2, varscan2
- PSG5 | c.477G>A p.R159= | Silent (SNP) | VAF 98/348 reads (28%) | catalogued as rs775127721, COSV100742697; called by muse, mutect2
- PSMA8 | c.51C>T p.H17= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100378651, COSV100378781; called by muse, mutect2, varscan2
- PTK2B | c.1356C>T p.I452= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as COSV100593743; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1515G>A p.K505= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100365281; called by muse, mutect2, varscan2
- RFC4 | c.42C>T p.P14= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs1405855086, COSV99961147, COSV99961285; called by muse, mutect2, varscan2
- RIC3 | c.363G>A p.G121= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV58305302; called by muse, mutect2, varscan2
- RP1 | c.144C>T p.F48= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as COSV55110759; called by muse, mutect2, varscan2
- RYR1 | c.6468C>T p.L2156= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs139714680, COSV100615410; called by muse, mutect2, varscan2
- SAMD15 | c.451C>T p.L151= | Silent (SNP) | VAF 63/161 reads (39%) | catalogued as COSV99374903; called by muse, mutect2, varscan2
- SCEL | c.822C>T p.F274= (on ENST00000349847 / NM_144777.3; = p.F254= on NM_003843.4) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1436830111, COSV100582821; called by muse, mutect2, varscan2
- SCN1A | c.1224C>T p.F408= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV57664475, COSV57679850; called by muse, mutect2
- SCPEP1 | c.435C>T p.L145= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs1304887082, COSV99227791; called by muse, mutect2, varscan2
- SEZ6L | c.2865G>A p.G955= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs1051954904, COSV50695025, COSV99961076; called by muse, mutect2, varscan2
- SIGLEC1 | c.1980C>T p.S660= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV99164049; called by muse, mutect2, varscan2
- SLC1A6 | c.1053C>T p.F351= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV55672335, COSV55673959; called by muse, mutect2, varscan2
- SLC22A14 | c.543G>A p.T181= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs769904501, COSV56198297; called by muse, mutect2, varscan2
- SLC39A12 | c.108C>T p.S36= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV101070019; called by muse, mutect2, varscan2
- SLC39A2 | c.169C>T p.L57= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100068534; called by muse, mutect2, varscan2
- SLC8A3 | c.138G>A p.E46= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100776088, COSV100776089; called by muse, mutect2, varscan2
- SLC9C1 | c.3309G>A p.R1103= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99997077, COSV99997745; called by muse, mutect2, varscan2
- SNX29 | c.933C>T p.F311= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as rs142950576; called by muse, mutect2, varscan2
- SP110 | c.1224C>T p.V408= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as COSV99283296; called by muse, mutect2, varscan2
- SPAG9 | c.3147C>T p.S1049= (on ENST00000262013 / NM_001130528.3; = p.S1035= on NM_003971.6) | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV100004967; called by muse, mutect2, varscan2
- SPATA31A1 | c.1443C>T p.P481= | Silent (SNP) | VAF 144/339 reads (42%) | called by muse, mutect2, varscan2
- SPDEF | c.84G>A p.L28= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100927767; called by muse, mutect2, varscan2
- SPPL2C | c.1453C>T p.L485= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as COSV100234011; called by muse, mutect2, varscan2
- SPTB | c.3183C>T p.S1061= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV67631764; called by muse, mutect2, varscan2
- STK36 | c.3183C>T p.T1061= | Silent (SNP) | VAF 58/188 reads (31%) | catalogued as COSV99831245; called by muse, mutect2, varscan2
- STOX2 | c.435C>T p.F145= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs545310273, COSV57853967, COSV57853994; called by muse, mutect2, varscan2
- STXBP5L | c.1158C>T p.L386= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV56508251; called by muse, mutect2, varscan2
- SULT2B1 | c.879C>T p.F293= (on ENST00000201586 / NM_177973.2; = p.F278= on NM_004605.2) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs780816664, COSV99572178; called by muse, varscan2
- TDGF1 | c.228G>A p.K76= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV99947351; called by muse, mutect2, varscan2
- TENM2 | c.2706C>T p.F902= (on ENST00000518659 / NM_001122679.2; = p.F670= on NM_001080428.3) | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV101318484; called by muse, mutect2, varscan2
- TINAG | c.1347G>A p.R449= | Silent (SNP) | VAF 106/204 reads (52%) | catalogued as COSV52511498; called by muse, mutect2, varscan2
- TLR4 | c.2331C>T p.T777= (on ENST00000355622 / NM_138554.5; = p.T737= on NM_003266.4) | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs957359839, COSV100842842, COSV62923583; called by muse, mutect2, varscan2
- TMEM31 | c.201G>A p.T67= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs750392195, COSV100129012, COSV60328268; called by muse, mutect2, varscan2
- TNK2 | c.1839C>T p.P613= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100361194; called by muse, mutect2, varscan2
- TONSL | c.3678G>A p.V1226= | Silent (SNP) | VAF 47/186 reads (25%) | catalogued as COSV99465528; called by muse, mutect2, varscan2
- TOX2 | c.1014G>A p.L338= (on ENST00000358131 / NM_001098798.2; = p.L314= on NM_032883.3) | Silent (SNP) | VAF 61/163 reads (37%) | catalogued as COSV100363728; called by muse, mutect2, varscan2
- TP63 | c.1662G>A p.A554= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs755622591, COSV53199834; called by muse, mutect2, varscan2
- TTN | c.61443A>G p.E20481= (on ENST00000591111; = p.E13057= on NM_003319.4) | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100605719; called by muse, mutect2, varscan2
- TTN | c.684C>T p.H228= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100605742; called by muse, mutect2, varscan2
- TUBAL3 | c.288C>T p.P96= | Silent (SNP) | VAF 55/119 reads (46%) | catalogued as rs368398918; called by muse, mutect2, varscan2
- WDR7 | c.627C>T p.S209= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs371036922; called by muse, mutect2, varscan2
- XKR3 | c.924C>T p.F308= | Silent (SNP) | VAF 35/149 reads (23%) | catalogued as COSV100509214; called by muse, mutect2, varscan2
- XYLB | c.1596G>A p.R532= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV99264114; called by muse, mutect2, varscan2
- ZEB1 | c.2029C>T p.L677= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs267602469, COSV100314152; called by muse, mutect2, varscan2
- ZFHX4 | c.2040A>G p.G680= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99261327; called by muse, mutect2, varscan2
- ZNF488 | c.159G>A p.T53= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs782635034; called by muse, mutect2, varscan2
- ZNF507 | c.1831T>C p.L611= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100321773; called by muse, varscan2
- ZNF527 | c.48C>T p.F16= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100648721; called by muse, mutect2, varscan2
- ZNF569 | c.174C>T p.F58= | Silent (SNP) | VAF 111/302 reads (37%) | catalogued as COSV100386420; called by muse, mutect2, varscan2
- AC073310.1 | n.596T>G | RNA (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084873 G>A | 5'Flank (SNP) | VAF 14/36 reads (39%) | catalogued as rs754943620, COSV100811014; called by muse, mutect2
- AL353804.4 | chrX:73824668 C>T | 5'Flank (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852007 G>A | 3'Flank (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- BTN2A3P | n.274C>T | RNA (SNP) | VAF 25/111 reads (23%) | catalogued as rs1190922740; called by muse, mutect2, varscan2
- CEP85L | c.*2C>G | 3'UTR (SNP) | VAF 41/93 reads (44%) | catalogued as rs371079398; called by muse, mutect2, varscan2
- COL27A1 | c.2269-240C>T | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as rs1257295882, COSV100620908; called by muse, mutect2, varscan2
- DUSP13 | c.*632C>T | 3'UTR (SNP) | VAF 60/142 reads (42%) | catalogued as rs771233970, COSV57816522; called by muse, mutect2, varscan2
- LIM2 | c.175+41G>A | Intron (SNP) | VAF 27/110 reads (25%) | catalogued as rs750765391, COSV99702326; called by muse, mutect2, varscan2
- OPRM1 | c.1164+1874G>A | Intron (SNP) | VAF 53/123 reads (43%) | catalogued as rs201186543, COSV100001027; called by muse, mutect2, varscan2
- RAVER1 | c.1431+162C>T | Intron (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99532568; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472182 G>A | 3'Flank (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
